Somatic mutation profile of tumor specimen C3N-02434-01 (aliquot CPT0115830009) from CPTAC case C3N-02434, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 74.2 years (27,102 days).
Specimen C3N-02434-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3eae1eb8-8687-4bc2-8f52-64d0763eab5f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02434-31 (Blood Derived Normal), aliquot CPT0116430002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/92c282e0-d010-4d13-b929-8f135c70f0d3

The open-access MAF lists 243 somatic variants for this specimen: 162 protein-altering or splice-affecting, 50 silent, 31 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 130, Silent 50, Nonsense Mutation 15, Intron 12, RNA 8, Frame Shift Del 8, 5'Flank 4, Splice Region 4, 3'UTR 3, 5'UTR 3, Splice Site 2, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.242G>T p.G81V | Missense Mutation (SNP) | VAF 132/293 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67960014, COSV67960167, COSV67960618; called by muse, mutect2, varscan2
- TP53 | c.536A>G p.H179R | Missense Mutation (SNP) | VAF 208/413 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1057519991, COSV52661025, COSV52661712, COSV52690692, COSV52937418; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AC244197.3 | c.417T>A p.N139K | Missense Mutation (SNP) | VAF 274/349 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CD031058; called by muse, mutect2, varscan2
- ACSL6 | c.91G>T p.V31L (on ENST00000379240; = p.V56L on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 258/485 reads (53%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV57300833; called by muse, mutect2, varscan2
- ANKRD30A | c.3208G>T p.E1070* (on ENST00000611781; = p.E1014* on NM_052997.2) | Nonsense Mutation (SNP) | VAF 26/56 reads (46%) | catalogued as rs767191588; called by muse, mutect2, varscan2
- ANKRD33 | c.538C>A p.L180M (on ENST00000340970 / NM_001304459.2; = p.L305M on NM_182608.4) | Missense Mutation (SNP) | VAF 84/519 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0.433); catalogued as COSV56605153; called by muse, mutect2, varscan2
- BNIP2 | c.540G>T p.Q180H | Missense Mutation (SNP) | VAF 45/128 reads (35%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.852); catalogued as rs757186206; called by muse, mutect2, varscan2
- C2CD3 | c.6283A>G p.S2095G | Missense Mutation (SNP) | VAF 33/150 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV100486826; called by muse, mutect2, varscan2
- C4BPB | c.95G>A p.S32N | Missense Mutation (SNP) | VAF 36/136 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.595); catalogued as COSV99700166; called by muse, mutect2, varscan2
- CACNA1D | c.3338C>T p.S1113L (on ENST00000350061 / NM_001128840.3; = p.S1133L on NM_000720.4) | Missense Mutation (SNP) | VAF 81/503 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1363939471, COSV55444282; called by muse, mutect2, varscan2
- CACNA1E | c.5077C>A p.R1693S | Missense Mutation (SNP) | VAF 55/259 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.053); catalogued as rs745342948, COSV62396016; called by muse, mutect2, varscan2
- CCDC85A | c.404G>T p.G135V | Missense Mutation (SNP) | VAF 300/413 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV68156638; called by muse, mutect2, varscan2
- CDHR1 | c.642T>C p.D214= | Splice Region (SNP) | VAF 173/401 reads (43%) | catalogued as COSV99058589; called by muse, mutect2, varscan2
- CFH | c.1312C>G p.P438A | Missense Mutation (SNP) | VAF 93/422 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.566); catalogued as COSV62776366; called by muse, mutect2, varscan2
- COL9A1 | c.1486G>T p.G496C | Missense Mutation (SNP) | VAF 156/500 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57891451; called by muse, mutect2, varscan2
- DCC | c.439G>T p.E147* | Nonsense Mutation (SNP) | VAF 62/243 reads (26%) | catalogued as COSV59083452; called by muse, mutect2, varscan2
- ELFN2 | c.709G>A p.A237T | Missense Mutation (SNP) | VAF 140/424 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as rs1404259609; called by muse, mutect2, varscan2
- F13B | c.1318G>C p.E440Q | Missense Mutation (SNP) | VAF 71/270 reads (26%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.721); catalogued as rs766408940, COSV66373657; called by muse, mutect2, varscan2
- FILIP1 | c.763C>A p.Q255K | Missense Mutation (SNP) | VAF 78/314 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV52739187; called by muse, mutect2, varscan2
- FMN2 | c.2185G>T p.E729* | Nonsense Mutation (SNP) | VAF 162/560 reads (29%) | catalogued as COSV60451271; called by muse, mutect2, varscan2
- GLT1D1 | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 24/231 reads (10%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs753834116; called by muse, mutect2, varscan2
- GPATCH1 | c.2345G>T p.G782V | Missense Mutation (SNP) | VAF 150/464 reads (32%) | SIFT tolerated (0.34); PolyPhen benign (0.039); catalogued as rs745713449; called by muse, mutect2, varscan2
- IFT52 | c.455T>C p.I152T | Missense Mutation (SNP) | VAF 101/304 reads (33%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs759737039; called by muse, mutect2, varscan2
- KLHDC7B | c.487G>A p.G163S (on ENST00000395676; = p.G804S on NM_138433.5) | Missense Mutation (SNP) | VAF 38/135 reads (28%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.011); catalogued as rs748205184; called by muse, mutect2, varscan2
- LILRA1 | c.122A>T p.Q41L | Missense Mutation (SNP) | VAF 58/178 reads (33%) | SIFT tolerated (0.61); PolyPhen benign (0.006); catalogued as rs762969311; called by muse, varscan2
- LIMCH1 | c.1798G>T p.G600W | Missense Mutation (SNP) | VAF 142/262 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV58291202; called by mutect2, varscan2
- MAP2K3 | c.504G>T p.E168D (on ENST00000342679 / NM_145109.3; = p.E139D on NM_002756.4) | Missense Mutation (SNP) | VAF 49/219 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV57568264; called by muse, mutect2, varscan2
- MRPS5 | c.890G>T p.R297I | Missense Mutation (SNP) | VAF 30/134 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.285); catalogued as rs1346164206, COSV55533315; called by muse, mutect2, varscan2
- MUC2 | c.3338C>T p.T1113M | Missense Mutation (SNP) | VAF 24/128 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs762204897; called by muse, mutect2, varscan2
- MYT1L | c.2195C>G p.T732S | Missense Mutation (SNP) | VAF 122/297 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV67727867; called by muse, mutect2, varscan2
- NCAM2 | c.961G>A p.V321I | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs371257511, COSV53099152; called by muse, mutect2, varscan2
- NELL1 | c.11A>G p.D4G | Missense Mutation (SNP) | VAF 130/341 reads (38%) | SIFT tolerated, low confidence (0.16); PolyPhen probably damaging (0.956); catalogued as rs1357332832; called by muse, mutect2, varscan2
- OR10X1 | c.290T>G p.M97R | Missense Mutation (SNP) | VAF 76/344 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1175975137; called by muse, mutect2, varscan2
- OR14K1 | c.284G>T p.C95F | Missense Mutation (SNP) | VAF 137/424 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1161501961, COSV51720335; called by muse, mutect2, varscan2
- OR2T2 | c.328G>T p.G110* | Nonsense Mutation (SNP) | VAF 153/862 reads (18%) | catalogued as COSV100737548, COSV61618333; called by mutect2, varscan2
- OR2T2 | c.329G>T p.G110V | Missense Mutation (SNP) | VAF 149/846 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770661335, COSV61617491, COSV61617669; called by mutect2, varscan2
- OR2T4 | c.98C>A p.T33N | Missense Mutation (SNP) | VAF 135/461 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV63544083, COSV63544305; called by muse, mutect2, varscan2
- OR51E2 | c.52G>T p.G18* | Nonsense Mutation (SNP) | VAF 27/114 reads (24%) | catalogued as COSV67807945; called by muse, mutect2, varscan2
- PKP4 | c.148C>T p.R50* | Nonsense Mutation (SNP) | VAF 74/130 reads (57%) | catalogued as rs921291987; called by muse, mutect2, varscan2
- PRSS16 | c.246G>C p.W82C | Missense Mutation (SNP) | VAF 11/148 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV57915523; called by muse, mutect2
- REXO1 | c.3538del p.L1180Sfs*30 | Frame Shift Del (DEL) | VAF 58/210 reads (28%) | catalogued as COSV50085473; called by mutect2, pindel*, varscan2
- RICTOR | c.545G>A p.R182K | Missense Mutation (SNP) | VAF 52/164 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.573); catalogued as COSV57127524; called by muse, mutect2, varscan2
- RYR2 | c.12188C>T p.T4063M | Missense Mutation (SNP) | VAF 84/368 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.787); catalogued as rs1214925323, COSV63665103; called by muse, mutect2, varscan2
- S1PR1 | c.799G>C p.A267P | Missense Mutation (SNP) | VAF 91/182 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV59512513; called by muse, mutect2, varscan2
- SCN3A | c.1534C>A p.L512I | Missense Mutation (SNP) | VAF 180/321 reads (56%) | SIFT tolerated (0.22); PolyPhen benign (0.025); catalogued as COSV51820778; called by muse, mutect2, varscan2
- SHANK1 | c.4888G>T p.E1630* | Nonsense Mutation (SNP) | VAF 24/77 reads (31%) | catalogued as COSV53253144; called by muse, mutect2, varscan2
- SLIT3 | c.1702A>T p.K568* | Nonsense Mutation (SNP) | VAF 70/139 reads (50%) | catalogued as COSV60633590; called by muse, mutect2, varscan2
- SPTA1 | c.1067G>A p.R356H | Missense Mutation (SNP) | VAF 121/330 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.767); catalogued as rs796158885; called by muse, mutect2, varscan2
- SSH1 | c.1903A>G p.I635V | Missense Mutation (SNP) | VAF 157/520 reads (30%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); catalogued as COSV58459490; called by muse, mutect2, varscan2
- TBC1D22A | c.1084G>A p.D362N | Missense Mutation (SNP) | VAF 102/791 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs760693157; called by muse, mutect2, varscan2
- TBX3 | c.718-7C>T | Splice Region (SNP) | VAF 30/279 reads (11%) | catalogued as COSV57472473; called by muse, mutect2, varscan2
- TICAM2 | c.41C>T p.S14F | Missense Mutation (SNP) | VAF 68/133 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.62); catalogued as rs762000950, COSV56694848; called by muse, mutect2, varscan2
- TMEM132D | c.3143C>A p.T1048N | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as COSV101242512; called by muse, varscan2
- TMEM255B | c.221G>A p.G74D | Missense Mutation (SNP) | VAF 34/174 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs574056507, COSV64704601; called by muse, mutect2, varscan2
- ZCCHC7 | c.748G>T p.G250C | Missense Mutation (SNP) | VAF 59/264 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100382821; called by muse, mutect2, varscan2
- ZNF567 | c.1583C>G p.T528R (on ENST00000536254 / NM_001322913.1; = p.T497R on NM_152603.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/167 reads (19%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as rs1466049188; called by muse, mutect2, varscan2
- ZNF638 | c.1502C>G p.S501* | Nonsense Mutation (SNP) | VAF 137/621 reads (22%) | catalogued as COSV52485577, COSV52493184; called by muse, mutect2, varscan2
- ZNF735 | c.29G>T p.S10I | Missense Mutation (SNP) | VAF 83/525 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as COSV70035631; called by muse, mutect2, varscan2
- ZNF99 | c.401A>G p.N134S | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.347); catalogued as COSV68055080; called by muse, mutect2
- ADPRH | c.149G>A p.R50K | Missense Mutation (SNP) | VAF 15/318 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ALPG | c.416A>G p.Q139R | Missense Mutation (SNP) | VAF 104/289 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.208); called by muse, mutect2, varscan2
- ALPK1 | c.2267A>T p.D756V | Missense Mutation (SNP) | VAF 34/63 reads (54%) | SIFT tolerated (0.23); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- ANO5 | c.22G>T p.E8* | Nonsense Mutation (SNP) | VAF 69/364 reads (19%) | called by muse, mutect2, varscan2
- APBB1IP | c.453G>A p.Q151= | Splice Region (SNP) | VAF 65/94 reads (69%) | called by muse, mutect2, varscan2
- ARHGAP30 | c.2861G>T p.C954F (on ENST00000368013 / NM_001025598.2; = p.C743F on NM_181720.3) | Missense Mutation (SNP) | VAF 14/370 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.593); called by muse, mutect2
- BCORL1 | c.214dup p.R72Pfs*22 | Frame Shift Ins (INS) | VAF 15/23 reads (65%) | called by mutect2, pindel, varscan2
- CACNA1H | c.5167G>T p.A1723S | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- CAGE1 | c.876T>G p.S292R (on ENST00000512086; = p.S156R on NM_205864.3) | Missense Mutation (SNP) | VAF 54/127 reads (43%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.663); called by muse, mutect2, varscan2
- CCDC138 | c.940T>G p.Y314D | Missense Mutation (SNP) | VAF 46/120 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- CGAS | c.449C>A p.A150D | Missense Mutation (SNP) | VAF 58/772 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.034); called by muse, mutect2
- CHD7 | c.3502G>C p.D1168H | Missense Mutation (SNP) | VAF 54/163 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- CLCN6 | c.739_745delinsA p.A247_G249delinsR | In Frame Del (DEL) | VAF 66/211 reads (31%) | called by pindel, varscan2*
- CLDN1 | c.124A>T p.T42S | Missense Mutation (SNP) | VAF 533/1056 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CLEC2L | c.192C>A p.D64E | Missense Mutation (SNP) | VAF 38/237 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- COL1A2 | c.2133+1G>T p.X711_splice | Splice Site (SNP) | VAF 318/757 reads (42%) | called by muse, mutect2, varscan2
- COMP | c.664del p.Q222Sfs*24 | Frame Shift Del (DEL) | VAF 171/657 reads (26%) | called by mutect2, pindel, varscan2
- CRIM1 | c.427A>G p.N143D | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- CTNNA2 | c.1343T>G p.V448G | Missense Mutation (SNP) | VAF 55/185 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CTR9 | c.1750G>T p.G584W | Missense Mutation (SNP) | VAF 37/226 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- CUX2 | c.3966C>A p.D1322E | Missense Mutation (SNP) | VAF 126/427 reads (30%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- CYLC2 | c.763G>A p.D255N | Missense Mutation (SNP) | VAF 47/99 reads (47%) | SIFT tolerated (0.3); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- DES | c.7C>T p.Q3* | Nonsense Mutation (SNP) | VAF 170/423 reads (40%) | called by muse, mutect2, varscan2
- DNAH11 | c.2335G>C p.E779Q | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.812); called by muse, mutect2
- DOK2 | c.524G>A p.G175E | Missense Mutation (SNP) | VAF 179/327 reads (55%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.526); called by muse, mutect2, varscan2
- DOT1L | c.3654G>T p.L1218F | Missense Mutation (SNP) | VAF 77/309 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.587); called by muse, mutect2, varscan2
- DUSP26 | c.350A>T p.E117V | Missense Mutation (SNP) | VAF 224/450 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- F13B | c.629-1G>C p.X210_splice | Splice Site (SNP) | VAF 5/41 reads (12%) | called by muse, mutect2
- FETUB | c.556C>A p.Q186K | Missense Mutation (SNP) | VAF 32/304 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- GJD4 | c.988C>G p.Q330E | Missense Mutation (SNP) | VAF 52/138 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- HNF4A | c.1393C>A p.Q465K | Missense Mutation (SNP) | VAF 92/330 reads (28%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- HNRNPUL1 | c.1864G>A p.G622S | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.827); called by muse, mutect2
- ICE1 | c.5315A>G p.N1772S | Missense Mutation (SNP) | VAF 130/420 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- IRS1 | c.2423C>T p.S808F | Missense Mutation (SNP) | VAF 82/197 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ITGAM | c.1463G>C p.G488A | Missense Mutation (SNP) | VAF 65/322 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNH7 | c.351C>A p.N117K | Missense Mutation (SNP) | VAF 56/115 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KHDRBS1 | c.61A>G p.M21V | Missense Mutation (SNP) | VAF 159/381 reads (42%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIAA1841 | c.2144G>T p.G715V | Missense Mutation (SNP) | VAF 89/288 reads (31%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- KIF26A | c.2683G>T p.A895S | Missense Mutation (SNP) | VAF 106/214 reads (50%) | SIFT tolerated (0.47); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- LCOR | c.728dup p.D244Gfs*28 | Frame Shift Ins (INS) | VAF 36/170 reads (21%) | called by mutect2, pindel, varscan2
- LIPC | c.941T>C p.L314P | Missense Mutation (SNP) | VAF 194/826 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- LRIT1 | c.311G>A p.R104Q | Missense Mutation (SNP) | VAF 197/488 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.019); called by mutect2, varscan2
- LRP1B | c.3226G>T p.E1076* | Nonsense Mutation (SNP) | VAF 80/281 reads (28%) | called by muse, mutect2, varscan2
- MTR | c.1306G>T p.A436S | Missense Mutation (SNP) | VAF 134/414 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- MUC12 | c.13295A>G p.D4432G (on ENST00000379442; = p.D4289G on NM_001164462.1) | Missense Mutation (SNP) | VAF 33/516 reads (6%) | SIFT tolerated (0.21); called by muse, mutect2
- MUC16 | c.30470T>C p.F10157S | Missense Mutation (SNP) | VAF 17/125 reads (14%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- MUC19 | c.875C>T p.P292L | Missense Mutation (SNP) | VAF 66/168 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- NALCN | c.2575A>G p.N859D | Missense Mutation (SNP) | VAF 43/161 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NELL1 | c.10G>T p.D4Y | Missense Mutation (SNP) | VAF 129/337 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- NUP133 | c.1563G>C p.L521F | Missense Mutation (SNP) | VAF 32/112 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- OR13A1 | c.913C>A p.P305T | Missense Mutation (SNP) | VAF 26/151 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- OR52B6 | c.236T>A p.M79K | Missense Mutation (SNP) | VAF 39/119 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- OR6F1 | c.120T>G p.S40R | Missense Mutation (SNP) | VAF 62/238 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- OR8S1 | c.916C>G p.H306D | Missense Mutation (SNP) | VAF 61/166 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- PABPC3 | c.1225C>G p.Q409E | Missense Mutation (SNP) | VAF 104/450 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.024); called by muse, varscan2
- PCDH15 | c.3347T>C p.L1116P | Missense Mutation (SNP) | VAF 37/75 reads (49%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- PCDHB3 | c.2164G>A p.V722M | Missense Mutation (SNP) | VAF 135/285 reads (47%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PCNX2 | c.35del p.G12Afs*56 | Frame Shift Del (DEL) | VAF 56/425 reads (13%) | called by mutect2, pindel, varscan2
- PEAK1 | c.4121G>A p.S1374N | Missense Mutation (SNP) | VAF 63/195 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PEAK1 | c.159C>A p.H53Q | Missense Mutation (SNP) | VAF 47/157 reads (30%) | SIFT tolerated (0.65); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PGM5 | c.1561C>A p.L521M | Missense Mutation (SNP) | VAF 121/240 reads (50%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- PIP4K2A | c.226A>G p.N76D | Missense Mutation (SNP) | VAF 58/103 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- POM121L2 | c.892C>A p.P298T | Missense Mutation (SNP) | VAF 214/375 reads (57%) | SIFT deleterious (0.02); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- PPIAL4A | c.261C>A p.N87K | Missense Mutation (SNP) | VAF 120/804 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.992); called by mutect2, varscan2
- PRDM16 | c.992A>T p.H331L | Missense Mutation (SNP) | VAF 111/253 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PRR23B | c.602C>A p.A201D | Missense Mutation (SNP) | VAF 28/148 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- RELN | c.7620del p.S2540Rfs*23 | Frame Shift Del (DEL) | VAF 86/459 reads (19%) | called by mutect2, pindel, varscan2
- RORA | c.160A>G p.S54G | Missense Mutation (SNP) | VAF 154/530 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.023); called by mutect2, varscan2
- SAGE1 | c.1022C>A p.A341D | Missense Mutation (SNP) | VAF 42/61 reads (69%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- SCN11A | c.2445C>A p.S815R | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, varscan2
- SELP | c.1660T>A p.C554S | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SEMA5A | c.85C>T p.Q29* | Nonsense Mutation (SNP) | VAF 83/297 reads (28%) | called by muse, mutect2, varscan2
- SERPINA6 | c.271C>G p.Q91E | Missense Mutation (SNP) | VAF 155/305 reads (51%) | SIFT tolerated (0.54); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SLC22A10 | c.664A>C p.T222P | Missense Mutation (SNP) | VAF 27/130 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- SLC6A13 | c.589G>T p.G197W | Missense Mutation (SNP) | VAF 83/355 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLCO1B3 | c.2061T>G p.D687E | Missense Mutation (SNP) | VAF 43/113 reads (38%) | SIFT tolerated (0.34); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SPDYE6 | c.254A>T p.E85V | Missense Mutation (SNP) | VAF 16/24 reads (67%) | SIFT tolerated (0.08); PolyPhen benign (0.177); called by mutect2, varscan2
- SPTB | c.2197G>T p.A733S | Missense Mutation (SNP) | VAF 217/465 reads (47%) | SIFT tolerated (0.21); PolyPhen benign (0.035); called by mutect2, varscan2
- TMCO3 | c.1539+4A>T | Splice Region (SNP) | VAF 32/105 reads (30%) | called by muse, mutect2, varscan2
- TOP1 | c.2165A>G p.N722S | Missense Mutation (SNP) | VAF 109/260 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.428); called by muse, mutect2, varscan2
- TTLL5 | c.119C>G p.P40R | Missense Mutation (SNP) | VAF 46/94 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- TTN | c.41593del p.D13865Ifs*8 (on ENST00000591111; = p.D6441Ifs*8 on NM_003319.4) | Frame Shift Del (DEL) | VAF 70/178 reads (39%) | called by mutect2, pindel, varscan2
- UNC13A | c.381del p.F127Lfs*5 | Frame Shift Del (DEL) | VAF 46/158 reads (29%) | called by mutect2, pindel, varscan2
- UNG | c.756G>T p.L252F (on ENST00000242576 / NM_080911.3; = p.L243F on NM_003362.4) | Missense Mutation (SNP) | VAF 185/669 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- VEGFA | c.619A>G p.K207E (on ENST00000523873 / NM_001171623.1; = p.K370E on NM_003376.6) | Missense Mutation (SNP) | VAF 763/1229 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- VWDE | c.3059C>G p.S1020C | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- WDR86 | c.551G>T p.C184F | Missense Mutation (SNP) | VAF 222/552 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- WRN | c.2496C>A p.D832E | Missense Mutation (SNP) | VAF 121/220 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZC2HC1B | c.228del p.K76Nfs*23 | Frame Shift Del (DEL) | VAF 12/76 reads (16%) | called by mutect2, pindel
- ZFP57 | c.1544G>T p.G515V | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT tolerated (0.22); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- ZNF224 | c.1948A>T p.K650* | Nonsense Mutation (SNP) | VAF 78/308 reads (25%) | called by muse, mutect2, varscan2
- ZNF273 | c.163G>A p.D55N | Missense Mutation (SNP) | VAF 20/332 reads (6%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.651); called by muse, mutect2
- ZNF324B | c.603G>C p.E201D | Missense Mutation (SNP) | VAF 141/583 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- ZNF479 | c.1048G>T p.E350* | Nonsense Mutation (SNP) | VAF 140/288 reads (49%) | called by muse, mutect2, varscan2
- ZNF519 | c.1097A>T p.H366L | Missense Mutation (SNP) | VAF 57/116 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ZNF541 | c.3170T>C p.I1057T | Missense Mutation (SNP) | VAF 77/182 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.356); called by muse, mutect2, varscan2
- ZNF568 | c.893G>T p.R298I | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF613 | c.776C>G p.P259R (on ENST00000293471 / NM_001031721.4; = p.P223R on NM_024840.4) | Missense Mutation (SNP) | VAF 21/233 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.006); called by muse, mutect2
- ZNF638 | c.1789C>T p.L597F | Missense Mutation (SNP) | VAF 76/325 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF682 | c.836A>G p.H279R | Missense Mutation (SNP) | VAF 61/143 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF865 | c.463del p.H155Tfs*8 | Frame Shift Del (DEL) | VAF 8/29 reads (28%) | called by mutect2, pindel, varscan2
- ZNF99 | c.983T>A p.L328H | Missense Mutation (SNP) | VAF 97/334 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNHIT2 | c.43G>T p.V15F | Missense Mutation (SNP) | VAF 26/140 reads (19%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.084); called by muse, mutect2
- ABCB7 | c.1104G>A p.L368= (on ENST00000373394 / NM_001271696.3; = p.L369= on NM_004299.6) | Silent (SNP) | VAF 51/74 reads (69%) | called by muse, mutect2, varscan2
- ABCG8 | c.921C>T p.I307= | Silent (SNP) | VAF 89/692 reads (13%) | catalogued as rs780422381, COSV55394886; called by muse, mutect2, varscan2
- ACTG1 | c.957C>G p.A319= | Silent (SNP) | VAF 247/686 reads (36%) | called by muse, mutect2, varscan2
- ANGPTL6 | c.948T>C p.Y316= | Silent (SNP) | VAF 40/123 reads (33%) | called by muse, mutect2, varscan2
- APOBEC3F | c.150C>T p.D50= | Silent (SNP) | VAF 27/397 reads (7%) | catalogued as rs776436739; called by muse, mutect2
- BCAT1 | c.1023T>A p.S341= | Silent (SNP) | VAF 62/157 reads (39%) | called by muse, mutect2, varscan2
- CTNNA3 | c.2484C>T p.A828= | Silent (SNP) | VAF 98/220 reads (45%) | catalogued as COSV101041217; called by muse, varscan2
- DCAF12L1 | c.1056C>A p.G352= | Silent (SNP) | VAF 72/108 reads (67%) | catalogued as COSV64421142, COSV64421668; called by muse, mutect2, varscan2
- DIP2A | c.861A>G p.P287= | Silent (SNP) | VAF 56/113 reads (50%) | called by muse, mutect2, varscan2
- ERBB3 | c.144A>G p.T48= | Silent (SNP) | VAF 223/724 reads (31%) | catalogued as rs764891356; called by muse, mutect2, varscan2
- FAM153B | c.606C>G p.V202= (on ENST00000253490; = p.V125= on NM_001265615.1) | Silent (SNP) | VAF 71/531 reads (13%) | catalogued as rs755374609; called by muse, mutect2, varscan2
- FBLN1 | c.51C>T p.L17= | Silent (SNP) | VAF 67/210 reads (32%) | called by muse, mutect2, varscan2
- GOLGA3 | c.96C>T p.G32= | Silent (SNP) | VAF 58/196 reads (30%) | catalogued as rs1442009469; called by muse, mutect2, varscan2
- GRIK5 | c.2655C>G p.L885= | Silent (SNP) | VAF 200/617 reads (32%) | catalogued as rs1555870277; called by muse, mutect2, varscan2
- HTR1B | c.822T>C p.V274= | Silent (SNP) | VAF 110/820 reads (13%) | called by muse, mutect2, varscan2
- ICAM5 | c.492G>C p.L164= | Silent (SNP) | VAF 274/852 reads (32%) | called by muse, mutect2, varscan2
- IL18R1 | c.522C>T p.N174= | Silent (SNP) | VAF 34/128 reads (27%) | catalogued as rs201629380; called by muse, mutect2, varscan2
- ITGAM | c.1464G>T p.G488= | Silent (SNP) | VAF 66/317 reads (21%) | called by muse, mutect2, varscan2
- ITPR2 | c.6993C>T p.G2331= | Silent (SNP) | VAF 102/272 reads (38%) | called by muse, varscan2
- LIG4 | c.12A>G p.S4= | Silent (SNP) | VAF 61/221 reads (28%) | called by muse, mutect2, varscan2
- LIPC | c.942G>T p.L314= | Silent (SNP) | VAF 194/824 reads (24%) | called by mutect2, varscan2
- LPAR3 | c.372C>T p.A124= | Silent (SNP) | VAF 91/170 reads (54%) | catalogued as rs368870250; called by muse, mutect2, varscan2
- LRFN2 | c.111G>T p.L37= | Silent (SNP) | VAF 13/64 reads (20%) | called by muse, mutect2, varscan2
- LTBP1 | c.2649C>A p.I883= (on ENST00000404816 / NM_206943.4; = p.I557= on NM_000627.4) | Silent (SNP) | VAF 39/200 reads (20%) | called by muse, mutect2, varscan2
- MCM5 | c.2136G>T p.L712= | Silent (SNP) | VAF 54/432 reads (13%) | catalogued as rs370537304; called by muse, mutect2, varscan2
- ME3 | c.1266G>A p.T422= | Silent (SNP) | VAF 17/182 reads (9%) | catalogued as rs749644334, COSV100661162; called by muse, mutect2
- MRPS5 | c.891A>G p.R297= | Silent (SNP) | VAF 31/135 reads (23%) | called by muse, mutect2, varscan2
- NCKAP1L | c.441G>T p.R147= | Silent (SNP) | VAF 81/271 reads (30%) | catalogued as COSV99515871; called by muse, mutect2, varscan2
- NCOA6 | c.153C>T p.A51= | Silent (SNP) | VAF 42/152 reads (28%) | catalogued as COSV62868496; called by muse, mutect2, varscan2
- NLGN1 | c.480C>G p.V160= | Silent (SNP) | VAF 48/143 reads (34%) | catalogued as COSV64327248; called by muse, mutect2, varscan2
- NLRP8 | c.1866A>T p.V622= | Silent (SNP) | VAF 32/117 reads (27%) | catalogued as COSV52586148; called by muse, mutect2, varscan2
- NOTCH3 | c.3534C>T p.H1178= | Silent (SNP) | VAF 55/419 reads (13%) | called by muse, mutect2, varscan2
- OCSTAMP | c.1185G>T p.R395= | Silent (SNP) | VAF 40/72 reads (56%) | catalogued as rs537737693; called by muse, mutect2, varscan2
- OR2C3 | c.360C>T p.S120= | Silent (SNP) | VAF 122/376 reads (32%) | called by muse, mutect2, varscan2
- OR6C75 | c.381T>A p.P127= | Silent (SNP) | VAF 98/291 reads (34%) | called by muse, mutect2, varscan2
- OR7C2 | c.415C>A p.R139= | Silent (SNP) | VAF 125/409 reads (31%) | called by muse, mutect2, varscan2
- POLR1G | c.849C>A p.V283= | Silent (SNP) | VAF 28/320 reads (9%) | called by muse, mutect2
- SCN1A | c.1506G>A p.K502= | Silent (SNP) | VAF 146/293 reads (50%) | called by muse, mutect2, varscan2
- SCRIB | c.3339C>T p.I1113= | Silent (SNP) | VAF 182/573 reads (32%) | called by muse, mutect2, varscan2
- SLC51A | c.237C>A p.T79= | Silent (SNP) | VAF 146/622 reads (23%) | called by muse, mutect2, varscan2
- STARD3 | c.1017C>T p.G339= | Silent (SNP) | VAF 15/83 reads (18%) | catalogued as rs776385927; called by muse, mutect2, varscan2
- THEGL | c.660G>T p.L220= | Silent (SNP) | VAF 84/159 reads (53%) | called by muse, mutect2, varscan2
- TMEM132C | c.1860A>G p.E620= | Silent (SNP) | VAF 57/360 reads (16%) | called by muse, mutect2, varscan2
- TMEM132D | c.2919G>T p.L973= | Silent (SNP) | VAF 28/232 reads (12%) | catalogued as COSV67160783; called by muse, varscan2
- TRAPPC9 | c.1062C>T p.V354= | Silent (SNP) | VAF 218/661 reads (33%) | catalogued as COSV66902275; called by muse, mutect2, varscan2
- TTN | c.70440C>A p.I23480= (on ENST00000591111; = p.I16056= on NM_003319.4) | Silent (SNP) | VAF 153/336 reads (46%) | catalogued as COSV100600377; called by muse, mutect2, varscan2
- ZFHX3 | c.1005C>A p.P335= | Silent (SNP) | VAF 33/223 reads (15%) | called by muse, mutect2, varscan2
- ZNF416 | c.978C>T p.Y326= | Silent (SNP) | VAF 22/226 reads (10%) | catalogued as rs138114602; called by muse, mutect2
- ZNF69 | c.183C>G p.T61= (on ENST00000429654 / NM_001364730.1; = p.T47= on NM_021915.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 59/168 reads (35%) | called by muse, mutect2, varscan2
- ZSCAN12 | c.966A>T p.I322= | Silent (SNP) | VAF 147/242 reads (61%) | called by muse, mutect2, varscan2
- AC136628.2 | n.182C>A | RNA (SNP) | VAF 71/158 reads (45%) | called by muse, mutect2, varscan2
- ADAM10 | c.207-10509G>T | Intron (SNP) | VAF 44/197 reads (22%) | called by muse, mutect2, varscan2
- AL162726.3 | n.255+83178G>T | Intron (SNP) | VAF 202/415 reads (49%) | called by mutect2, varscan2
- AP1S3 | c.*39_*42del | 3'UTR (DEL) | VAF 7/38 reads (18%) | catalogued as rs200257231; called by pindel, varscan2
- CAGE1 | c.2005-307A>G | Intron (SNP) | VAF 4/38 reads (11%) | called by muse, mutect2
- CARD19 | c.*1214C>T | 3'UTR (SNP) | VAF 44/276 reads (16%) | catalogued as rs376622480; called by muse, varscan2
- CCDC188 | c.733-19T>C | Intron (SNP) | VAF 7/40 reads (18%) | catalogued as rs73150876; called by muse, mutect2
- CEACAM3 | c.425-1649A>G | Intron (SNP) | VAF 120/413 reads (29%) | catalogued as rs782168877; called by muse, varscan2
- CLC | c.-34A>G | 5'UTR (SNP) | VAF 39/135 reads (29%) | called by muse, mutect2, varscan2
- CLEC4A | c.299-1223G>T | Intron (SNP) | VAF 192/526 reads (37%) | called by muse, mutect2, varscan2
- HSPA7 | n.902G>A | RNA (SNP) | VAF 188/705 reads (27%) | catalogued as rs746309497; called by muse, mutect2, varscan2
- IL16 | c.-227C>T | 5'UTR (SNP) | VAF 72/337 reads (21%) | called by muse, mutect2, varscan2
- IRF2 | c.529+937A>T | Intron (SNP) | VAF 145/271 reads (54%) | called by muse, mutect2, varscan2
- MIR519C | n.84G>C | RNA (SNP) | VAF 40/126 reads (32%) | called by muse, mutect2, varscan2
- MIR6511A1 | chr16:14929312 C>A | 3'Flank (SNP) | VAF 152/1192 reads (13%) | catalogued as rs201513913; called by muse, mutect2, varscan2
- MUC2 | chr11:1099486 G>T | 5'Flank (SNP) | VAF 34/446 reads (8%) | called by muse, mutect2
- NAGK | chr2:71068570 C>T | 5'Flank (SNP) | VAF 26/372 reads (7%) | catalogued as rs945978590; called by muse, mutect2
- NCKAP5L | c.193-18G>C | Intron (SNP) | VAF 185/538 reads (34%) | called by muse, mutect2, varscan2
- OR2M1P | n.516G>C | RNA (SNP) | VAF 89/321 reads (28%) | called by muse, mutect2, varscan2
- PKD1P6 | n.4518+107A>T | Intron (SNP) | VAF 165/464 reads (36%) | catalogued as rs1168707911; called by muse, mutect2, varscan2
- PSG9 | c.1243+89C>A | Intron (SNP) | VAF 47/74 reads (64%) | called by muse, mutect2, varscan2
- RBBP4 | c.*2079G>T | 3'UTR (SNP) | VAF 59/105 reads (56%) | catalogued as rs768823697; called by muse, mutect2, varscan2
- SLC5A5 | c.1171+29G>T | Intron (SNP) | VAF 202/590 reads (34%) | called by muse, mutect2, varscan2
- SNORD116-16 | n.64A>T | RNA (SNP) | VAF 171/496 reads (34%) | called by muse, mutect2
- SNORD116-16 | n.66A>C | RNA (SNP) | VAF 166/485 reads (34%) | called by muse, mutect2
- SNRPN | c.-14G>A | 5'UTR (SNP) | VAF 31/414 reads (7%) | catalogued as COSV100578043; called by muse, mutect2
- SPATA31C1 | n.2377C>G | RNA (SNP) | VAF 69/407 reads (17%) | called by muse, mutect2, varscan2
- THSD7B | c.140-65525C>G | Intron (SNP) | VAF 24/216 reads (11%) | catalogued as rs1365790698, COSV55648494; called by muse, mutect2, varscan2
- TRAV22 | chr14:22066276 C>A | 5'Flank (SNP) | VAF 103/160 reads (64%) | called by muse, mutect2, varscan2
- USP2 | chr11:119381840 C>A | 5'Flank (SNP) | VAF 75/384 reads (20%) | called by muse, mutect2, varscan2
- ZNF849P | n.431C>A | RNA (SNP) | VAF 25/157 reads (16%) | catalogued as rs1047657703; called by muse, mutect2, varscan2
